Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PC-01A from TCGA case TCGA-VQ-A8PC, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.5 years (23,912 days).
Specimen TCGA-VQ-A8PC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1e2d4a37-e2c1-4b61-b877-53e13e84d2d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b9a6e327-0062-4e73-ae58-679dc8a0d1c0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,492; copy number 2: 13,969; copy number 3: 14,241; copy number 4: 20,494; copy number 5: 4,846; copy number 6: 2,643; copy number 7: 1,453; copy number 8: 476; copy number 9: 195; copy number 17: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PC-01A-11D-A396-01): tumor purity 0.34, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 198 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,560,606–158,612,514, 3 genes, copy number 17: OR6P1, OR10X1, OR10Z1.
- chr7:816,615–3,302,452, 62 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:3,337,889–3,338,601, 1 gene, copy number 9: AC092427.1.
- chr17:30,115,521–30,186,475, 1 gene, copy number 9 (within-gene range 6–9): NSRP1.
- chr17:30,194,319–32,945,106, 131 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 620. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
